Somatic mutation profile of tumor specimen TARGET-10-PASPDS-09A (aliquot TARGET-10-PASPDS-09A-01D) from TARGET case TARGET-10-PASPDS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.9 years (3,990 days).
Specimen TARGET-10-PASPDS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 360862cd-c40a-4f4b-9786-08963d1ce25e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASPDS-14A (Bone Marrow Normal), aliquot TARGET-10-PASPDS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a47b2928-3fcf-4371-8eb2-c34c0c6c37e2

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL2L14 | c.88T>C p.Y30H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53796668; called by muse, mutect2, varscan2
- CIITA | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs773228525, COSV60863531; called by muse, mutect2, varscan2
- COL12A1 | c.5873C>A p.P1958Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV59411771; called by muse, mutect2, varscan2
- CR1L | c.282A>T p.K94N | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1429710611, COSV54332755; called by muse, mutect2, varscan2
- CTNNA1 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV57083002; called by muse, mutect2, varscan2
- CTNND2 | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as rs140086280; called by muse, mutect2
- FMNL2 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV56507305; called by muse, mutect2, varscan2
- LYST | c.5062G>A p.A1688T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV67716066; called by muse, mutect2, varscan2
- PTEN | c.696dup p.R233Tfs*10 | Frame Shift Ins (INS) | VAF 6/60 reads (10%) | catalogued as CI147229, COSV64305740; called by mutect2, varscan2
- SCAF11 | c.2663C>T p.S888F | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs372088219, COSV65477110; called by muse, mutect2, varscan2
- SPATA31D1 | c.1774C>A p.L592I | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.759); catalogued as COSV100782382, COSV61202671; called by muse, mutect2
- SVBP | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV65301366; called by muse, mutect2, varscan2
- TRIOBP | c.3536G>A p.R1179H | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs771635907, COSV60375876; called by muse, mutect2, varscan2
- DGCR8 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by mutect2, varscan2
- ZNF586 | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CHRNB2 | c.981C>T p.T327= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV63808172; called by muse, mutect2, varscan2
- ELAPOR1 | c.354C>T p.L118= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs147894230; called by muse, mutect2, varscan2
- KIDINS220 | c.825C>T p.G275= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as rs371218344, COSV56755562; called by muse, mutect2, varscan2
- PRUNE2 | c.2385G>A p.A795= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs367561759, COSV65045440; called by muse, mutect2, varscan2
- PTEN | c.697C>A p.R233= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: likely benign; called by mutect2, varscan2
